Gene-level copy-number profile of tumor specimen TCGA-WK-A8XS-01A from TCGA case TCGA-WK-A8XS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 58.9 years (21,521 days).
Specimen TCGA-WK-A8XS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.103bdc11-8aa9-486c-ba84-cad23e72c603.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WK-A8XS-10E (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10e7675a-a1d8-45a8-952e-4e8f4780668b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 214; copy number 2: 15,276; copy number 3: 13,280; copy number 4: 28,204; copy number 5: 2,011; copy number 6: 605; copy number 7: 15; copy number 9: 175.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WK-A8XS-01A-11D-A37B-01): tumor purity 0.84, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–49,793,307, 35 genes (within-gene range 0–1): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 175 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:113,791,829–116,249,497, 24 genes, copy number 9 (within-gene range 4–9): FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213, DNAJA1P4, AL138830.2, AL138830.1, AL590550.1, RNU6-475P, AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3.
- chr17:11,241,213–11,564,063, 1 gene, copy number 9 (within-gene range 6–9): SHISA6.
- chr17:11,598,470–17,042,305, 149 genes, copy number 9 (broad region; genes not listed).
- chr17:17,076,038–17,077,752, 1 gene, copy number 9: MPRIP-AS1.

Autosomal genes at a single copy (total copy number 1): 214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
